Surgical pathology report (de-identified scan), TCGA case TCGA-FL-A1YV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii - Normal Study, specimen TCGA-FL-A1YV-11A (Solid Tissue Normal).

[page 1 of 2]
Surgical Pathology Report

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED]
DOB: [REDACTED]
Gender: F
Physician(s): [REDACTED]
cc: [REDACTED]

Client: [REDACTED]
Location: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

History/Clinical Dx: Right adnexal mass

Postoperative Dx: Same, pending pathology examination

1CD-0-3 not applicable

Specimen(s) Received:

A: Right ovarian cyst
B: Uterus, cervix, left ovary and tube

Normal path from non-cancer patient.

for 11/11/11

DIAGNOSIS:

A. Right ovarian cyst: Benign serous cystadenoma

B. Uterus, cervix, left ovary and tube:

Cervix:	Chronic inflammation
Endometrium:	inactive
Myometrium:	Adenomyosis
Right ovary:	Serous inclusions
Right tube:	Unremarkable

Intraoperative Consultation:

Gross intraoperative: Right ovarian cyst: Benign

Gross Description

A. Specimen A is received fresh labeled right ovarian cyst and consists of a cystically dilated ovary weighing 47 gm and measuring 11.0 x 5.5 x 2.0 cm. The cyst is received open. The external surface of the cyst is tan and smooth. An attached fallopian tube measures 8.6 cm in length and 0.5 cm in diameter. A small, tan-yellow-tan excrescence is attached to the cyst lining measuring 0.3 cm in greatest dimension. Otherwise the cyst lining is smooth.

Representative sections are submitted as follows: representative section of ovary and fallopian tube are submitted in cassettes A1-A3.

B. Received in formalin fixative labeled uterus, cervix, left ovary and tube and consists of a previously opened uterus with a attached left adnexal structures weighing altogether 39 gm. The serosal surface is tan and smooth. The uterine corpus measures 4.0 x 3.5 x 2.5 cm. The cervix measures 3.0 cm in length and 2.5 cm in diameter. A single small cystic structure is

Regulatory Statement:

The following statement may be applicable to some of the reagents/instruments used in developing the above report. This test was developed and is performed in a laboratory that has been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that each element of equipment is not necessary. This test is used for clinical purposes. It should not be performed as a means of diagnosis or for research. The laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 2]
[REDACTED]

Surgical Pathology Report

[REDACTED]

present on the endometrial surface measuring 0.3 cm. The remaining endometrium is tan-pink and smooth. Serial sectioning of the myometrium reveals no grossly identifiable lesions. The endo- and ectocervical mucosa is unremarkable. The left ovary measures 3.0 cm in greatest length. Cut section reveals a smooth-walled cyst containing serous fluid measuring 1.4 cm in greatest dimension. The attached fallopian tube measures 5.5 cm in length and 0.5 cm in diameter. Representative sections are submitted as follows: B1 cervix, B2 and B3 endo/myometrium, B4 left adnexal structures.

Microscopic Description

A&B. The microscopic findings support the above diagnoses.

[REDACTED]

Source: NCI Genomic Data Commons file 5517f36b-03e1-4f0d-aa7a-57498327ca1b (TCGA-FL-A1YV.DE7868BF-DA24-4C11-B331-6064E4CCCEAF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).